OHSU case 1704 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3a9bf07a-4b9c-4fc7-bb91-572253c675b9

Demographics
Sex at birth: male; Vital status: Dead.

Diagnoses (1)
1. Atypical chronic myeloid leukemia, BCR/ABL negative: ICD-O-3 morphology code: 9876/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Age at diagnosis: 66.0 years (24,106 days); Days to last follow up: 155 days.

Biospecimens (1 sample)
- Sample 4939D: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
